Somatic mutation profile of tumor specimen TCGA-VR-AA7I-01A (aliquot TCGA-VR-AA7I-01A-11D-A403-09) from TCGA case TCGA-VR-AA7I, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 70.8 years (25,855 days).
Specimen TCGA-VR-AA7I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb6d374d-d1d8-4968-aa79-5cf893b7e67e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-AA7I-10A (Blood Derived Normal), aliquot TCGA-VR-AA7I-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17658d3f-3332-489e-9538-e4f2c0de8ced

The open-access MAF lists 121 somatic variants for this specimen: 92 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 28, Frame Shift Ins 5, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSS3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54100594; called by muse, mutect2, varscan2
- APOB | c.7837C>A p.Q2613K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as COSV51951071; called by muse, mutect2
- ATF7IP | c.3451C>G p.L1151V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53767398; called by muse, mutect2, varscan2
- C17orf78 | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs750590762; called by muse, mutect2, varscan2
- C6orf58 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs780579826, COSV100314770, COSV61667508; called by muse, mutect2, varscan2
- CCER1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as COSV62646551; called by muse, mutect2, varscan2
- COL6A1 | c.2506G>A p.G836S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1315626031; called by muse, mutect2, varscan2
- CSMD3 | c.8315G>A p.G2772E (on ENST00000297405 / NM_001363185.1; = p.G2603E on NM_052900.3) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52146136; called by muse, mutect2, varscan2
- DCAF12L1 | c.1370A>G p.N457S | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV100948078; called by muse, mutect2, varscan2
- DGCR8 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV61228289; called by muse, mutect2
- DNAH8 | c.7639G>T p.E2547* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV59438908; called by muse, mutect2, varscan2
- FAM71B | c.304T>C p.W102R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1196470336; called by muse, mutect2, varscan2
- GALNT14 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.49); catalogued as rs955498267, COSV61110731; called by muse, mutect2, varscan2
- GRIA3 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 88/176 reads (50%) | catalogued as COSV52079805; called by muse, mutect2, varscan2
- HSP90AB1 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs199811663; called by muse, mutect2, varscan2
- KLHL38 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs763669952, COSV58088341; called by muse, mutect2, varscan2
- MC4R | c.949A>T p.I317F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs778685158, CM052897; called by muse, mutect2, varscan2
- MPP1 | c.1099C>A p.H367N | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV65730299; called by muse, mutect2
- OR11H1 | c.631A>T p.I211F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs775913492; called by muse, mutect2, varscan2
- OR5J2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs909570306, COSV56623450; called by muse, mutect2, varscan2
- PRICKLE1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs1457774536, COSV61543203; called by muse, mutect2, varscan2
- SLC22A1 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.037); catalogued as rs760456949; called by muse, mutect2, varscan2
- SLITRK3 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs756131997, COSV53845789; called by muse, mutect2, varscan2
- SNED1 | c.2592C>A p.C864* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs778898633; called by muse, mutect2
- TAS2R50 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1487400860, COSV67854823; called by muse, mutect2, varscan2
- TASOR | c.1729C>T p.P577S (on ENST00000355628 / NM_001365636.2; = p.P181S on NM_015224.3) | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1293289558; called by muse, mutect2, varscan2
- TBX4 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs370445781; called by muse, mutect2, varscan2
- UBE3D | c.767A>G p.Q256R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV52753991, COSV52756642; called by muse, mutect2, varscan2
- VAPA | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.584); catalogued as COSV61297362; called by muse, mutect2, varscan2
- VWF | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs778742589, COSV54632336; called by muse, mutect2, varscan2
- ZNF587 | c.1441A>G p.I481V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs762919845; called by muse, mutect2, varscan2
- AAAS | c.949_956dup p.W319Cfs*37 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- ADCY7 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMY1B | c.1002G>A p.R334= | Splice Region (SNP) | VAF 16/134 reads (12%) | called by mutect2, varscan2
- ARPP21 | c.1058T>G p.L353R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ATP11B | c.1707dup p.L570Sfs*4 | Frame Shift Ins (INS) | VAF 20/162 reads (12%) | called by mutect2, pindel, varscan2
- ATP9A | c.2927G>T p.W976L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BICD2 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CCHCR1 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCA2 | c.783A>C p.E261D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CLDN9 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- CLEC14A | c.155A>C p.E52A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CNTNAP3 | c.3855_3858del p.E1286Sfs*26 | Frame Shift Del (DEL) | VAF 106/600 reads (18%) | called by mutect2, pindel, varscan2
- COBLL1 | c.3378G>C p.Q1126H (on ENST00000392717; = p.Q1088H on NM_014900.5) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DHX32 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DTNB | c.1763T>A p.L588Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.5861A>C p.E1954A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.146); called by muse, mutect2
- EN1 | c.956A>C p.K319T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- EPN1 | c.1209G>C p.E403D (on ENST00000270460 / NM_001321263.1; = p.E377D on NM_013333.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLT3LG | c.221G>A p.W74* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- IGHV3-49 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- KCNG4 | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KDM6B | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KRT14 | c.774_786del p.A259Rfs*18 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- LFNG | c.714G>T p.E238D (on ENST00000222725 / NM_001040167.2; = p.E109D on NM_002304.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- LRFN5 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MAGEB4 | c.875T>G p.V292G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAGEC1 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MAP2 | c.5299C>T p.H1767Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MCOLN3 | c.444C>A p.N148K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLX | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MSH6 | c.562_563insGAAGA p.I188Rfs*25 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- MUC16 | c.22023dup p.T7342Yfs*32 | Frame Shift Ins (INS) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- MYH8 | c.2437G>T p.A813S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MZT2B | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- NLRC5 | c.2881C>A p.L961I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.276); called by mutect2, varscan2
- OR51L1 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH9 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PITX2 | c.647C>G p.S216C (on ENST00000354925 / NM_001204397.1; = p.S223C on NM_000325.6) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRKAB2 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKAR2B | c.1121del p.L374* | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- PTPN9 | c.1299T>A p.N433K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SEC24B | c.470A>T p.N157I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- STOML2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SYT12 | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.035); called by muse, mutect2
- TAF1 | c.2918C>A p.A973E (on ENST00000373790 / NM_138923.4; = p.A994E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TFCP2 | c.936C>G p.H312Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2
- TMEM182 | c.74T>G p.F25C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TRPC4 | c.2575C>A p.Q859K (on ENST00000379705 / NM_016179.4; = p.Q864K on NM_003306.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPM4 | c.2068A>T p.I690F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.54920T>C p.L18307P (on ENST00000591111; = p.L10883P on NM_003319.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TTN | c.42749T>C p.I14250T (on ENST00000591111; = p.I6826T on NM_003319.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- USPL1 | c.2534A>G p.H845R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, varscan2
- VHLL | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.401); called by muse, mutect2
- VPS9D1 | c.1124A>G p.D375G | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP2 | c.9557A>C p.N3186T (on ENST00000628543; = p.N3361T on NM_152381.6) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ZFC3H1 | c.3709A>G p.I1237V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF160 | c.2339dup p.M780Ifs*13 | Frame Shift Ins (INS) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- ZNF460 | c.740A>T p.N247I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF70 | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ZWILCH | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ADGRV1 | c.17127C>T p.F5709= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- ARID1B | c.5001C>T p.L1667= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs766430210, COSV51670346; called by muse, mutect2, varscan2
- ASTN1 | c.1800G>T p.P600= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56074653; called by muse, mutect2, varscan2
- BCLAF1 | c.534G>A p.P178= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs369195148, COSV62142934; called by muse, mutect2
- CCT2 | c.777C>T p.D259= | Silent (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2
- CMTM8 | c.429G>T p.A143= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- COL15A1 | c.3210A>C p.T1070= | Silent (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- DHX35 | c.1533C>T p.I511= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs534416816, COSV99326249; called by muse, mutect2, varscan2
- DRD2 | c.69C>T p.N23= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs200831689, COSV100669688; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM227B | c.615C>T p.S205= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV54812135; called by muse, mutect2, varscan2
- FBXL7 | c.231G>A p.S77= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs561477427, COSV61644605; called by muse, mutect2, varscan2
- FCRL2 | c.93A>G p.G31= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- FNDC1 | c.1561C>A p.R521= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- GABRA1 | c.717T>G p.V239= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- GCC2 | c.387A>G p.K129= | Silent (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- KLHDC7A | c.2313T>C p.D771= | Silent (SNP) | VAF 4/35 reads (11%) | called by mutect2, varscan2
- KLHL32 | c.1569T>C p.T523= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- LRRK1 | c.3498G>T p.P1166= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV52625644; called by muse, mutect2, varscan2
- RYR2 | c.12216G>A p.T4072= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs746200625, COSV100772134, COSV63702567; called by muse, mutect2, varscan2
- SBF1 | c.5484G>A p.E1828= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- SEMA3C | c.1092T>C p.I364= | Silent (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- SHANK1 | c.2469C>T p.D823= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs369883291; called by muse, mutect2, varscan2
- SLC38A8 | c.213C>T p.S71= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs149748570; called by muse, mutect2
- SLC44A1 | c.1923C>T p.V641= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs151307942; called by muse, mutect2, varscan2
- SYCP3 | c.393T>C p.T131= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- USP24 | c.3541C>T p.L1181= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1036512307; called by muse, mutect2, varscan2
- USP43 | c.2178C>T p.T726= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV53307778; called by muse, mutect2, varscan2
- ZBTB46 | c.507G>A p.P169= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs374159825; called by muse, mutect2, varscan2
- PARP3 | c.-135G>C | 5'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
